Somatic mutation profile of tumor specimen TCGA-DU-7015-01A (aliquot TCGA-DU-7015-01A-11D-2024-08) from TCGA case TCGA-DU-7015, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.2 years (15,041 days).
Specimen TCGA-DU-7015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 887bc51f-f244-427a-93ba-bdfa9e8d1486.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7015-10B (Blood Derived Normal), aliquot TCGA-DU-7015-10B-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a98d804-6451-4117-9062-db5cd1f3fafd

The open-access MAF lists 32 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 3, Nonsense Mutation 2, RNA 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 34/45 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACBD3 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as rs920198834, COSV64729552, COSV64731342; called by muse, mutect2, varscan2
- B3GNT5 | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as rs1182054494, COSV58476328, COSV58477135; called by muse, mutect2, varscan2
- C3 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1348311492, COSV55581886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH19 | c.1320T>G p.I440M | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV50978970; called by muse, mutect2
- CHST1 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV57325904; called by muse, mutect2, varscan2
- COL12A1 | c.6560A>G p.Q2187R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59408876; called by muse, mutect2, varscan2
- DBR1 | c.813T>G p.H271Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.769); catalogued as COSV53431269; called by muse, mutect2
- EDA | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs182251004, COSV58879175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNPTAB | c.3647T>C p.L1216P | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73418410; called by muse, mutect2, varscan2
- GRIA1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.027); catalogued as rs138238382, COSV53607690; called by muse, mutect2, varscan2
- MYH4 | c.4907C>A p.A1636D | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs868761997, COSV55120383; called by muse, mutect2, varscan2
- NKX2-1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1447379564, CM086002, COSV61390372; called by muse, mutect2
- OR52D1 | c.566G>C p.R189P | Missense Mutation (SNP) | VAF 79/169 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV59488410; called by muse, mutect2, varscan2
- OR5B21 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV64482298; called by muse, mutect2
- PDCD2L | c.346A>G p.N116D | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV55826734, COSV99874998; called by muse, mutect2, varscan2
- PPP1R26 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs868578127, COSV63357483; called by muse, mutect2
- RBM23 | c.1177G>A p.A393T (on ENST00000359890 / NM_001077351.2; = p.A377T on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.599); catalogued as rs562925583; called by muse, mutect2
- SYBU | c.143C>T p.P48L (on ENST00000276646 / NM_001099754.2; = p.P47L on NM_017786.6) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV52623270; called by muse, mutect2
- TBATA | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs374343305; called by muse, mutect2, varscan2
- TG | c.5341A>T p.T1781S | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV55095537; called by muse, mutect2, varscan2
- WWC3 | c.1317G>T p.Q439H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.544); catalogued as COSV66507802; called by muse, mutect2, varscan2
- ATRX | c.791del p.Y264Ffs*24 | Frame Shift Del (DEL) | VAF 106/197 reads (54%) | called by mutect2, pindel, varscan2
- HHIPL2 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 15/532 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2
- IGHV3-43 | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PRR12 | c.958G>T p.D320Y (on ENST00000615927; = p.D1141Y on NM_020719.3) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADNP | c.2814T>C p.T938= | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as rs764863978, COSV62426948; called by muse, mutect2
- CSMD3 | c.9624T>C p.N3208= (on ENST00000297405 / NM_001363185.1; = p.N3039= on NM_052900.3) | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV52328902; called by muse, mutect2
- ORC4 | c.252C>T p.L84= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV51577332; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83097A>G | Intron (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- MIR133B | n.105C>T | RNA (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
